Somatic mutation profile of tumor specimen ALCH-B40C-TTP1-A (aliquot ALCH-B40C-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B40C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.8 years (25,116 days).
Specimen ALCH-B40C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a2dc590-ae34-4d93-ab14-fbc65a2c1937.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B40C-NB1-A (Blood Derived Normal), aliquot ALCH-B40C-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8b0c34d-8528-4d6e-a0ec-7e4bae23b064

The open-access MAF lists 173 somatic variants for this specimen: 121 protein-altering or splice-affecting, 29 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 29, Intron 12, Nonsense Mutation 12, 3'UTR 4, Splice Site 3, RNA 3, Translation Start Site 2, Splice Region 2, 5'Flank 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 36/312 reads (12%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANGPTL7 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs901100424, COSV100816801; called by muse, mutect2
- ANKS4B | c.1171C>G p.P391A | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479933536; called by muse, mutect2
- ATP1A2 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1463299098, COSV100767592; called by muse, mutect2
- CENPL | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0.081); catalogued as COSV61891369; called by muse, mutect2, varscan2
- CHIA | c.985C>T p.Q329* (on ENST00000343320; = p.Q221* on NM_021797.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/272 reads (7%) | catalogued as COSV58474271; called by muse, mutect2
- CHST2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV58885279; called by muse, mutect2, varscan2
- COPS3 | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs1000406382; called by muse, mutect2
- CUBN | c.8237C>G p.S2746C | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV64711448; called by muse, mutect2
- CUZD1 | c.1761C>G p.I587M | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100158647; called by muse, mutect2
- DNAH7 | c.10195G>A p.E3399K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV56765367; called by muse, mutect2, varscan2
- DPAGT1 | c.1162-8C>G | Splice Region (SNP) | VAF 33/428 reads (8%) | catalogued as COSV53830477; called by muse, mutect2
- ELK3 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 59/405 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1063997; called by muse, mutect2, varscan2
- EPS8L2 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs1380250447, COSV59349357; called by muse, mutect2
- FCRL1 | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100839878; called by muse, mutect2
- FGF6 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1477139038; called by muse, mutect2
- FLG | c.9695C>A p.S3232Y | Missense Mutation (SNP) | VAF 132/709 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV100910253; called by muse, mutect2, varscan2
- GLIS1 | c.1832G>A p.G611D | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1355922030; called by muse, mutect2
- GPER1 | c.1089C>G p.S363R | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as rs1269756130; called by muse, mutect2, varscan2
- KIF2B | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs757684038, COSV52133696; called by muse, mutect2
- KLHL40 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 21/333 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV55134585; called by muse, mutect2
- KMT2D | c.9142G>C p.D3048H | Missense Mutation (SNP) | VAF 76/873 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99986125; called by muse, mutect2
- MGRN1 | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs375630510, COSV52149159; called by muse, mutect2
- NLRC4 | c.597C>G p.F199L | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61591549; called by muse, mutect2
- NUP188 | c.4535C>T p.S1512L | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs868844273; called by muse, mutect2, varscan2
- PAPPA2 | c.4975G>C p.E1659Q | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.269); catalogued as rs767285867; called by muse, varscan2
- PCDHB15 | c.905G>C p.R302P | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs782684982, COSV51425681; called by muse, mutect2
- PLB1 | c.3098G>C p.R1033T | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs985209548; called by muse, mutect2
- RPE65 | c.371G>C p.R124P | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV52013547, COSV52015838, COSV52016741; called by muse, mutect2, varscan2
- RPS6KL1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs866027458; called by muse, mutect2
- SLC30A8 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as COSV101438606; called by muse, mutect2
- SMOC2 | c.74C>G p.S25W | Missense Mutation (SNP) | VAF 19/423 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1400313432; called by muse, mutect2
- TNNI2 | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV53290158; called by muse, mutect2, varscan2
- TOX | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs367546486; called by muse, mutect2
- TP53 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 24/404 reads (6%) | catalogued as rs1555524156, COSV52716070, COSV52776099; ClinVar: uncertain significance; called by muse, mutect2
- TSHZ3 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1568367246, COSV53662974; called by muse, mutect2
- USH2A | c.10822C>A p.L3608M | Missense Mutation (SNP) | VAF 29/358 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV100244200; called by muse, mutect2
- ZFPM1 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs1306360154; called by muse, mutect2
- ZIC3 | c.1349C>G p.T450S | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54975434; called by muse, mutect2, varscan2
- ZNFX1 | c.3589C>T p.L1197F | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780228891; called by muse, mutect2, varscan2
- AHNAK2 | c.12106C>T p.L4036F | Missense Mutation (SNP) | VAF 38/545 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2
- AMIGO1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2
- ANHX | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ANK1 | c.229-1G>C p.X77_splice | Splice Site (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- ANO10 | c.1095C>G p.I365M | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2
- ARFGEF1 | c.2942G>T p.R981I | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP21 | c.2030T>G p.V677G | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASB15 | c.1332G>T p.M444I | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- ASTN1 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.158); called by muse, mutect2
- CACHD1 | c.3600G>C p.M1200I | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2
- CMYA5 | c.5086G>T p.A1696S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL25A1 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- COPS8 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CTTNBP2NL | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CWF19L2 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYB561D1 | c.345G>C p.R115S | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DDX27 | c.994C>G p.Q332E | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DENND11 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2
- DLGAP1 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); called by muse, mutect2
- DMRTB1 | c.280A>C p.S94R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2
- DNAAF5 | c.1120G>T p.G374W | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- DNAH10 | c.5730G>C p.L1910F (on ENST00000409039; = p.L1849F on NM_207437.3) | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DYSF | c.5269C>T p.Q1757* | Nonsense Mutation (SNP) | VAF 44/508 reads (9%) | called by muse, mutect2
- FOLR2 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 36/418 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- FYTTD1 | c.498-1G>C p.X166_splice | Splice Site (SNP) | VAF 8/71 reads (11%) | called by muse, varscan2
- GPR132 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); called by muse, mutect2
- GPR137 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- HARS1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 30/353 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.138); called by muse, mutect2
- HIPK1 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | called by muse, varscan2
- HUWE1 | c.77T>A p.L26H | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- INTS6 | c.99G>C p.E33D | Missense Mutation (SNP) | VAF 26/363 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ITPRID1 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JAKMIP2 | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- KCNJ3 | c.544A>T p.I182F | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- KEAP1 | c.785dup p.Y263Lfs*87 | Frame Shift Ins (INS) | VAF 44/367 reads (12%) | called by mutect2, pindel, varscan2
- KIF19 | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- KIF26B | c.4177G>T p.V1393F | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- KLK10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2
- L3MBTL4 | c.220-1G>T p.X74_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- LHCGR | c.1905T>A p.F635L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- LRRC1 | c.1541A>T p.N514I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MST1R | c.2831G>C p.R944T | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.049); called by muse, varscan2
- MTA1 | c.1940G>C p.R647P | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MTARC1 | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 18/315 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); called by muse, mutect2
- MUC16 | c.33299C>A p.P11100H | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NAV2 | c.6916G>A p.V2306M (on ENST00000396087 / NM_001244963.2; = p.V2247M on NM_145117.5) | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- NFE2L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- NKAPD1 | c.483G>C p.Q161H (on ENST00000280352 / NM_001082970.2; = p.Q162H on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- NOL8 | c.653A>C p.K218T | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- NRK | c.2712G>T p.W904C | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PHLPP1 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- PLEKHG6 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- PLXNA1 | c.677C>G p.S226* | Nonsense Mutation (SNP) | VAF 44/419 reads (11%) | called by muse, mutect2, varscan2
- POU3F3 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- PPP1R13B | c.2851G>C p.D951H | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBBP5 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2
- RELN | c.9539A>G p.Y3180C | Missense Mutation (SNP) | VAF 34/569 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RP1L1 | c.1489G>T p.G497W | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RTP3 | c.581C>G p.S194* | Nonsense Mutation (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- RUFY3 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- RYR3 | c.1575T>G p.A525= | Splice Region (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- SCAF11 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2
- SDK1 | c.1880A>T p.E627V | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); called by muse, mutect2
- SEMA3A | c.1684G>C p.D562H | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SEPTIN14 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SLC34A2 | c.1867_1881del p.R623_R627del | In Frame Del (DEL) | VAF 37/278 reads (13%) | called by pindel, varscan2
- SLC8A1 | c.1043T>G p.L348* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- SORL1 | c.6267G>T p.M2089I | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- SPATA2L | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- SPEF1 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 30/292 reads (10%) | called by muse, mutect2
- SPTBN5 | c.6034G>T p.A2012S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- TAS2R7 | c.836C>G p.S279* | Nonsense Mutation (SNP) | VAF 16/161 reads (10%) | called by muse, mutect2
- TCTE3 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TEAD4 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- UNC13A | c.3634C>G p.Q1212E | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VWDE | c.356T>G p.L119W | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- WBP11 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- WIPI2 | c.291G>T p.R97S | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- WWP2 | c.674C>A p.S225* | Nonsense Mutation (SNP) | VAF 46/300 reads (15%) | called by muse, mutect2, varscan2
- ZNF2 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- ZNF721 | c.2530A>G p.R844G (on ENST00000338977; = p.R856G on NM_133474.4) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ABLIM1 | c.1404A>T p.P468= | Silent (SNP) | VAF 35/198 reads (18%) | called by muse, mutect2, varscan2
- AHNAK2 | c.7248C>G p.L2416= | Silent (SNP) | VAF 22/384 reads (6%) | catalogued as rs756285959, COSV60926851; called by muse, mutect2
- ANKRD40 | c.675C>G p.S225= | Silent (SNP) | VAF 24/323 reads (7%) | called by muse, mutect2
- BMPER | c.849G>A p.E283= | Silent (SNP) | VAF 59/488 reads (12%) | called by muse, mutect2, varscan2
- C16orf71 | c.1332G>A p.K444= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs1346062069; called by muse, mutect2
- ECT2L | c.1404G>A p.L468= | Silent (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- EGFR | c.2406C>A p.V802= | Silent (SNP) | VAF 34/486 reads (7%) | catalogued as COSV51803208; called by muse, mutect2
- ERN2 | c.1968G>A p.V656= | Silent (SNP) | VAF 54/330 reads (16%) | called by muse, mutect2, varscan2
- F7 | c.267G>A p.E89= | Silent (SNP) | VAF 14/358 reads (4%) | called by muse, mutect2
- FOXJ1 | c.1038C>T p.L346= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- FRMD5 | c.579G>C p.L193= | Silent (SNP) | VAF 14/205 reads (7%) | called by muse, mutect2
- GAD1 | c.1224C>T p.G408= | Silent (SNP) | VAF 34/307 reads (11%) | catalogued as rs375640311; called by muse, mutect2, varscan2
- GPR83 | c.123C>T p.F41= | Silent (SNP) | VAF 32/450 reads (7%) | called by muse, mutect2
- KIT | c.276C>A p.T92= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as COSV99853634; called by muse, mutect2, varscan2
- LCE2A | c.222C>A p.P74= | Silent (SNP) | VAF 92/429 reads (21%) | called by muse, mutect2, varscan2
- LMTK2 | c.1503G>A p.T501= | Silent (SNP) | VAF 19/216 reads (9%) | catalogued as rs368766168; called by muse, mutect2
- MMP17 | c.1071G>C p.L357= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV62181210; called by muse, mutect2
- MYNN | c.1540T>C p.L514= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- NAGPA | c.243C>T p.F81= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV56569187; called by muse, mutect2
- NSF | c.1644G>A p.G548= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- PDE10A | c.1866G>T p.V622= | Silent (SNP) | VAF 37/266 reads (14%) | called by muse, mutect2, varscan2
- PIK3C2G | c.112C>T p.L38= | Silent (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- PIWIL2 | c.1854T>G p.A618= | Silent (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- PXMP4 | c.42C>T p.V14= | Silent (SNP) | VAF 34/332 reads (10%) | catalogued as rs199736156; called by muse, mutect2, varscan2
- SLC22A6 | c.432G>C p.G144= | Silent (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- SLC25A20 | c.102C>G p.V34= | Silent (SNP) | VAF 34/428 reads (8%) | called by muse, mutect2
- TMPRSS13 | c.885C>T p.I295= | Silent (SNP) | VAF 34/261 reads (13%) | called by muse, mutect2, varscan2
- WSCD1 | c.420C>T p.H140= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as rs1360132383; called by muse, mutect2
- ZNF821 | c.318A>T p.T106= (on ENST00000425432 / NM_001376297.1; = p.T64= on NM_017530.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/214 reads (10%) | called by muse, mutect2, varscan2
- ASL | c.656-40C>T | Intron (SNP) | VAF 20/286 reads (7%) | called by muse, mutect2
- BTN2A3P | n.1686C>G | RNA (SNP) | VAF 23/458 reads (5%) | called by muse, mutect2
- CALCA | chr11:14967746 G>C | 3'Flank (SNP) | VAF 21/284 reads (7%) | called by muse, mutect2
- CALM3 | chr19:46600916 G>C | 5'Flank (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- CCDC187 | c.*2523C>G | 3'UTR (SNP) | VAF 47/174 reads (27%) | called by muse, mutect2, varscan2
- CRAMP1 | c.3102+13C>T | Intron (SNP) | VAF 14/229 reads (6%) | called by muse, mutect2
- CYP11B1 | c.240-159A>T | Intron (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- E2F7 | c.988+374G>T | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- HDAC8 | c.437+134G>A | Intron (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+5917G>T | Intron (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- LINC00917 | n.1564+1523C>T | Intron (SNP) | VAF 30/249 reads (12%) | catalogued as rs774528420; called by muse, mutect2, varscan2
- MEIS1 | c.*72G>T | 3'UTR (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
- MIR9-3 | n.13C>T | RNA (SNP) | VAF 30/472 reads (6%) | called by muse, mutect2
- POR | c.-4-10088C>G | Intron (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100792802; called by muse, mutect2
- RNA5-8SP2 | chr16:34159599 G>A | 5'Flank (SNP) | VAF 6/76 reads (8%) | catalogued as rs1433220021; called by muse, mutect2
- RPL7A | c.-10G>T | 5'UTR (SNP) | VAF 60/239 reads (25%) | called by mutect2, varscan2
- STMN4 | c.510+47T>C | Intron (SNP) | VAF 15/276 reads (5%) | called by muse, mutect2
- TBX3 | c.718-17C>T | Intron (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- TENM3 | c.511+102116C>T | Intron (SNP) | VAF 22/401 reads (5%) | catalogued as rs1265105858; called by muse, mutect2
- TF | c.*8G>C | 3'UTR (SNP) | VAF 30/374 reads (8%) | called by muse, mutect2
- TMSB10 | c.*8G>C | 3'UTR (SNP) | VAF 10/176 reads (6%) | catalogued as COSV99252776; called by muse, mutect2
- UBE2DNL | n.136C>T | RNA (SNP) | VAF 21/167 reads (13%) | catalogued as rs1412304545; called by muse, mutect2, varscan2
- USP34 | c.7596-11T>C | Intron (SNP) | VAF 7/51 reads (14%) | catalogued as rs767786296; called by muse, mutect2, varscan2
